Surgical pathology report (de-identified scan), TCGA case TCGA-22-4594, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-4594-01A (Primary Tumor).

Surgical Pathology

TISSUE DESCRIPTION:

Left upper lobe lung (190 grams; 21 x 11 x 5 cm) and superior (paratracheal) and inferior (subcarinal) mediastinal, left pulmonary artery and left lower lobe lung lymph nodes

DIAGNOSIS:

Lung, left upper lobe, lobectomy: Grade 4 (of 4) squamous cell carcinoma, forming a 4.2 x 4.0 x 3.5 cm peripheral mass, invading through the pleura into the chest wall soft tissue. The bronchial and chest wall resection margins are negative for malignancy. 2 (of 4) intrapulmonary peribronchial lymph nodes are positive for metastatic squamous cell carcinoma.

Lymph nodes, superior mediastinal (paratracheal), excision: Metastatic grade 4 (of 4) squamous cell carcinoma in 2 (of 4) lymph nodes.

Lymph nodes, inferior mediastinal (subcarinal), left pulmonary artery and left lower lobe lung, excision: Multiple inferior mediastinal (3 subcarinal), left pulmonary artery (6) and left lower lobe lung (6) lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file 87cc422b-4ab2-4a64-b11d-bdd1125a4457 (TCGA-22-4594.FC15B2EA-BEAD-452D-9857-7380FF2ED628.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).